Somatic mutation profile of tumor specimen C3N-00516-01 (aliquot CPT0078090007_1) from CPTAC case C3N-00516, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.9 years (25,164 days).
Specimen C3N-00516-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8d11e47-203f-4461-b5c2-9efbefcd8ebb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00516-31 (Blood Derived Normal), aliquot CPT0078150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b4a03d8-1f01-413d-a7d9-b4803b95829c

The open-access MAF lists 52 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 4, RNA 3, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 168/692 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 222/801 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- B4GALNT4 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1430980375; called by muse, mutect2, varscan2
- COL13A1 | c.1736C>T p.P579L (on ENST00000398978 / NM_001130103.2; = p.P507L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs766119482; called by muse, mutect2, varscan2
- CSMD1 | c.5309C>T p.P1770L (on ENST00000520002; = p.P1769L on NM_033225.6) | Missense Mutation (SNP) | VAF 165/872 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771790436; called by muse, mutect2, varscan2
- DSCAM | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1432629129, COSV68648785; called by muse, mutect2, varscan2
- FBXW5 | c.634dup p.I212Nfs*53 | Frame Shift Ins (INS) | VAF 116/401 reads (29%) | catalogued as rs762193986; called by mutect2, pindel, varscan2
- FTCD | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 46/867 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as rs201966668; called by muse, mutect2
- GPR158 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 97/579 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372238950, COSV66267514; called by muse, mutect2, varscan2
- JAG2 | c.3016C>T p.R1006W | Missense Mutation (SNP) | VAF 65/854 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1358299413; called by muse, mutect2
- KIR2DL3 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as rs770288421; called by muse, mutect2
- LUM | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57129387; called by muse, mutect2
- MYC | c.665C>G p.S222C (on ENST00000377970; = p.S237C on NM_002467.6) | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV52373051; called by muse, mutect2, varscan2
- MYO1F | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs758097575, COSV57792161; called by muse, mutect2
- PIGQ | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 83/471 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs752541286, COSV50314907; called by muse, mutect2, varscan2
- RASGRP4 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 124/553 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769519232, COSV53039354; called by muse, mutect2, varscan2
- SCUBE2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 36/678 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370871651; called by muse, mutect2
- SMARCA1 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1318171945, COSV100946432; called by muse, mutect2, varscan2
- SNTG2 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 199/906 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs768494785; called by muse, mutect2, varscan2
- TRIM42 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 54/1020 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1250313209, COSV53883465; called by muse, mutect2
- ZNF33B | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 48/646 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369377643; called by muse, mutect2
- ARFGEF2 | c.4536A>C p.L1512F | Missense Mutation (SNP) | VAF 44/786 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- GLB1 | c.1375A>G p.N459D | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- HEG1 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 70/720 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- KCNJ9 | c.439T>G p.S147A | Missense Mutation (SNP) | VAF 133/768 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KRT23 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MRI1 | c.557G>C p.R186P | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTAP | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 74/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR1M1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 57/549 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PGR | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 56/525 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM3 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 129/552 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC5A4 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 187/854 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRIO | c.6301G>T p.V2101L | Missense Mutation (SNP) | VAF 57/395 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF226 | c.1766G>A p.C589Y | Missense Mutation (SNP) | VAF 140/470 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP5 | c.138C>T p.H46= | Silent (SNP) | VAF 82/825 reads (10%) | catalogued as rs773535817, COSV100895669; called by muse, mutect2, varscan2
- CAPN3 | c.1077G>A p.P359= | Silent (SNP) | VAF 154/708 reads (22%) | catalogued as rs759384108, COSV100532508; called by muse, mutect2, varscan2
- DGKZ | c.3009C>T p.G1003= (on ENST00000454345 / NM_001105540.2; = p.G815= on NM_003646.4) | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as rs148565335; called by muse, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 35/532 reads (7%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2
- GID8 | c.165C>T p.I55= | Silent (SNP) | VAF 67/318 reads (21%) | catalogued as rs965129217; called by muse, mutect2, varscan2
- GTF3C1 | c.1596G>A p.P532= | Silent (SNP) | VAF 48/361 reads (13%) | catalogued as rs781464590, COSV62239574; called by muse, mutect2, varscan2
- H2BC21 | c.210C>T p.I70= | Silent (SNP) | VAF 38/1136 reads (3%) | catalogued as rs1225639259; called by muse, mutect2
- OR4C3 | c.297C>A p.L99= | Silent (SNP) | VAF 14/437 reads (3%) | catalogued as rs1439981435, COSV60586876; called by muse, mutect2
- RASAL1 | c.894G>A p.L298= | Silent (SNP) | VAF 24/488 reads (5%) | catalogued as COSV55655439; called by muse, mutect2
- THSD7B | c.3891C>T p.T1297= (on ENST00000272643; = p.T1295= on NM_001316349.2) | Silent (SNP) | VAF 40/514 reads (8%) | called by muse, mutect2
- CCDC7 | c.1454+2595G>A | Intron (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- CMAHP | n.1745T>C | RNA (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- ECM1 | c.385+35C>T | Intron (SNP) | VAF 22/531 reads (4%) | called by muse, mutect2
- H2BP2 | n.1061+1853C>A | Intron (SNP) | VAF 63/802 reads (8%) | called by muse, mutect2
- HSP90AA4P | n.1732dup | RNA (INS) | VAF 42/252 reads (17%) | catalogued as rs70944383; called by pindel, varscan2
- MICAL3 | c.2241+1577_2241+1578insG | Intron (INS) | VAF 33/255 reads (13%) | called by mutect2, pindel*, varscan2*
- SLC30A8 | chr8:117135321 G>A | 5'Flank (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- SPATA31C1 | n.2324A>T | RNA (SNP) | VAF 270/996 reads (27%) | called by muse, mutect2, varscan2
